TARGET case TARGET-20-ECandCBtransferexp-ECplusTAH002-ECcells — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/d0b9a9e1-3ca9-482d-b067-156234f8736f

Biospecimens (1 sample)
- Sample TARGET-20-ECandCBtransferexp-ECplusTAH002-ECcells-85: Sample type: Next Generation Cancer Model; Tissue type: Tumor.
